TARGET case TARGET-10-PARVBY — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d833a0c4-9f3a-52f3-9e3f-a0dc8941ed85

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 2.7 years (970 days); Year of diagnosis: 2008; Days to last follow up: 2,425 days (6.6 years); Sites of involvement: Testes.
   Treatment given: Protocol identifier: AALL0232.

Follow-up (1 entry)
- Days to follow up: 2,425 days (6.6 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,425; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Positive.
- Trisomy 4: Positive.
- Day 0: Leukocytes 15.9 ×10³/µL.
- Day 8: Bone Marrow blast count 41%; Minimal Residual Disease (Flow Cytometry) 2.4%.
- Day 15: Bone Marrow blast count 0%.
- Day 29: Bone Marrow blast count 2%; Minimal Residual Disease (Flow Cytometry) 0.0085%.

Biospecimens (2 samples)
- Sample TARGET-10-PARVBY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARVBY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PARVBY-09A-01D:
- Blast %: 89

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 2425
- WBC at Diagnosis: 15.9
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: Yes
- MRD Day 8: 2.4
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.0085
- MRD Day 29 Sensitivity: 0.0085
- MRD End Consolidation Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- TRISOMY 4 10 Status: Positive
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 41
- BMA Blasts Day 15: 0
- BMA Blasts Day 29: 2
- Karyotype: 56,XY,+X,+4,+6,+9,+10,+14,+18,+21,+21[5]/46,XY[17]
- Down Syndrome: No
- DNA Index: 1.2038
- Cell of Origin: B Cell ALL
